Somatic mutation profile of tumor specimen TCGA-77-8150-01A (aliquot TCGA-77-8150-01A-11D-2244-08) from TCGA case TCGA-77-8150, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 64.3 years (23,474 days).
Specimen TCGA-77-8150-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d0afb5d-a10a-495b-90d8-3f608c3d7a11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8150-10A (Blood Derived Normal), aliquot TCGA-77-8150-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6614769c-d2e4-45ea-a33f-f1f490b3fc3b

The open-access MAF lists 141 somatic variants for this specimen: 107 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 30, Frame Shift Del 9, Nonsense Mutation 8, Frame Shift Ins 3, Splice Region 2, In Frame Del 2, RNA 2, Translation Start Site 1, Splice Site 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5907_5908del p.R1970Sfs*6 (on ENST00000358273 / NM_001042492.3; = p.R1949Sfs*6 on NM_000267.3) | Frame Shift Del (DEL) | VAF 35/81 reads (43%) | catalogued as rs863224835; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3010A>G p.M1004V | Missense Mutation (SNP) | VAF 27/98 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV55914513; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 46/61 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM28 | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99737993; called by muse, mutect2, varscan2
- ADAMTS4 | c.852T>A p.S284R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV100917370; called by muse, mutect2, varscan2
- ADAMTS7 | c.372C>A p.H124Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV101183032; called by muse, mutect2
- AGPS | c.1496A>G p.D499G | Missense Mutation (SNP) | VAF 122/262 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV99931104; called by muse, mutect2, varscan2
- AKAP9 | c.11706T>A p.D3902E (on ENST00000359028; = p.D3878E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99133649; called by muse, mutect2, varscan2
- ANKRD50 | c.4069A>T p.K1357* | Nonsense Mutation (SNP) | VAF 75/115 reads (65%) | catalogued as COSV101538897; called by muse, mutect2, varscan2
- ARFGEF3 | c.2420G>T p.S807I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV99292616, COSV99293422; called by muse, mutect2, varscan2
- ASTN2 | c.1268G>A p.R423H (on ENST00000313400 / NM_001365069.1; = p.R372H on NM_014010.5) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); catalogued as rs149596951; called by muse, mutect2, varscan2
- ATP4A | c.156T>A p.I52= | Splice Region (SNP) | VAF 94/307 reads (31%) | catalogued as COSV99382231; called by muse, mutect2, varscan2
- BRINP2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV100837893; called by muse, mutect2
- CAMTA1 | c.2563G>T p.A855S | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.154); catalogued as COSV100346886; called by muse, mutect2, varscan2
- CCDC110 | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100293725; called by muse, mutect2, varscan2
- CFHR2 | c.468C>A p.D156E | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV100804265; called by muse, mutect2, varscan2
- CGA | c.49G>C p.V17L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV100851661; called by muse, mutect2
- CHRM2 | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278120022, COSV100280848; called by muse, mutect2, varscan2
- CIITA | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100161483; called by muse, mutect2, varscan2
- CKB | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs1428642510, COSV100818908; called by muse, mutect2
- CRYBG3 | c.6241T>G p.Y2081D | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99476668; called by muse, mutect2, varscan2
- CTNNA3 | c.2675G>C p.R892T | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV101041263, COSV65523579; called by muse, mutect2, varscan2
- CUL3 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100023865; called by muse, mutect2, varscan2
- CUL5 | c.1018T>C p.Y340H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101263640; called by muse, mutect2, varscan2
- DCAF4L2 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | catalogued as COSV100150573, COSV60476409; called by muse, mutect2, varscan2
- DNAH8 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); catalogued as rs754133293, COSV100543679, COSV100545147; ClinVar: uncertain significance; called by muse, varscan2
- DNHD1 | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV99599565; called by muse, mutect2, varscan2
- DPEP2 | c.966C>A p.N322K | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as rs182720433, COSV99263073; called by muse, mutect2, varscan2
- DPP6 | c.1297C>A p.Q433K (on ENST00000377770 / NM_001364500.2; = p.Q371K on NM_001936.5) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100123583; called by muse, varscan2
- EPHA8 | c.1001A>T p.N334I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99384387; called by muse, mutect2, varscan2
- ERLIN2 | c.336C>A p.D112E | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV99379467; called by muse, mutect2, varscan2
- EYS | c.1185-1G>C p.X395_splice | Splice Site (SNP) | VAF 8/15 reads (53%) | catalogued as COSV60985818; called by muse, mutect2, varscan2
- F10 | c.1265C>A p.P422Q | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM042982, COSV100979152, COSV65021331; called by muse, mutect2, varscan2
- FAM135A | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV99525376; called by muse, mutect2, varscan2
- FSIP2 | c.20555G>C p.G6852A | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.274); catalogued as COSV100554294; called by muse, mutect2, varscan2
- GAD2 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV99392698; called by muse, mutect2, varscan2
- GALNT2 | c.1357G>T p.G453* | Nonsense Mutation (SNP) | VAF 91/342 reads (27%) | catalogued as COSV100795515; called by muse, mutect2, varscan2
- GNB4 | c.652T>A p.C218S | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); catalogued as COSV99224094; called by muse, mutect2, varscan2
- GPN3 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99959474; called by muse, mutect2, varscan2
- GPR141 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV57731421; called by muse, mutect2, varscan2
- HERPUD2 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV100257834; called by muse, mutect2, varscan2
- HHIPL2 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | catalogued as COSV100596656; called by muse, mutect2, varscan2
- IGHV3-38 | c.105dup p.S36Vfs*15 | Frame Shift Ins (INS) | VAF 29/247 reads (12%) | catalogued as rs748218659; called by mutect2, pindel, varscan2
- IRAK3 | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); catalogued as rs780513721, COSV99705987; called by muse, mutect2, varscan2
- ITGA8 | c.688A>T p.T230S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV100958960; called by muse, mutect2, varscan2
- KCNK9 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100270485; called by muse, mutect2, varscan2
- KCNMB2 | c.643G>C p.A215P | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); catalogued as COSV100843855; called by muse, mutect2, varscan2
- KDM1B | c.1348A>T p.M450L (on ENST00000449850; = p.M318L on NM_153042.4) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99924018; called by muse, mutect2, varscan2
- KIAA1109 | c.12904G>T p.G4302W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.907); catalogued as COSV99146732; called by muse, mutect2, varscan2
- LAMA2 | c.7835G>C p.R2612T | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as COSV101370217; called by muse, mutect2, varscan2
- LAMB2 | c.2410T>C p.C804R | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565060; called by muse, mutect2, varscan2
- LHX8 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as COSV99633190; called by muse, mutect2, varscan2
- LRRK2 | c.2124A>T p.L708F | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.721); catalogued as rs760381722, COSV54153441; called by muse, mutect2, varscan2
- MANEA | c.1131C>G p.I377M | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); catalogued as COSV100721458, COSV62589751; called by muse, mutect2, varscan2
- MDN1 | c.11108C>A p.S3703* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as COSV101020868; called by muse, mutect2, varscan2
- MED1 | c.1072A>T p.N358Y | Missense Mutation (SNP) | VAF 57/79 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV100327509; called by muse, mutect2, varscan2
- MFF | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.324); catalogued as rs781133574, COSV100449272; called by muse, mutect2, varscan2
- MGLL | c.611G>A p.G204E (on ENST00000398104 / NM_001003794.2; = p.G214E on NM_007283.6) | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99411576; called by muse, mutect2, varscan2
- MUC5B | c.3721C>A p.Q1241K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV101500075; called by muse, mutect2, varscan2
- NFKBIZ | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756636549, COSV58200654; called by muse, mutect2, varscan2
- NSD1 | c.3586G>T p.V1196L | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100728551; called by muse, mutect2, varscan2
- OGDHL | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs757087426, COSV65105583; called by muse, mutect2, varscan2
- OR2B3 | c.478T>C p.S160P | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101013756; called by muse, mutect2
- OR5D18 | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.392); catalogued as COSV61736614; called by muse, mutect2, varscan2
- PACS2 | c.290_292del p.S97del | In Frame Del (DEL) | VAF 23/173 reads (13%) | catalogued as rs782429503; called by mutect2, pindel, varscan2
- PARVB | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.34); catalogued as rs1569131326, COSV100114578, COSV58688033, COSV58692157; called by muse, mutect2, varscan2
- PDE7B | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.517); catalogued as rs377744382, COSV57495491; called by muse, mutect2, varscan2
- PLCXD2 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV67341562; called by muse, mutect2, varscan2
- PLEKHH3 | c.2214G>T p.E738D | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.967); catalogued as COSV52217524, COSV52218251; called by muse, mutect2, varscan2
- PNPLA8 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV99993439; called by muse, mutect2, varscan2
- PPFIBP1 | c.2181G>A p.W727* (on ENST00000318304 / NM_177444.3; = p.W721* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 64/103 reads (62%) | catalogued as COSV99944414; called by muse, mutect2, varscan2
- PRUNE2 | c.5894C>T p.P1965L | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100944271; called by muse, mutect2, varscan2
- PURG | c.478T>G p.S160A | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.165); catalogued as COSV99988429; called by muse, mutect2, varscan2
- PYGL | c.2389G>T p.A797S | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs902208339, COSV99368324; called by muse, mutect2, varscan2
- RNF208 | c.434C>G p.T145S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1328604052, COSV100763092, COSV100763112; called by mutect2, varscan2
- RPL10L | c.340G>T p.G114C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100022420, COSV53561284; called by muse, mutect2, varscan2
- RPS6KC1 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100873795; called by muse, mutect2, varscan2
- SLC12A1 | c.2473C>A p.L825I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV66800362; called by muse, mutect2, varscan2
- SLC1A6 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as rs753442710, COSV55672015; called by muse, mutect2, varscan2
- SLC6A17 | c.1448C>A p.T483K | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100521122; called by muse, mutect2, varscan2
- SLITRK3 | c.2116C>A p.H706N | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0.013); catalogued as rs776015238, COSV99578687; called by muse, mutect2, varscan2
- SPAM1 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99772763; called by muse, mutect2, varscan2
- SPATA31D1 | c.1052T>A p.L351H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100782542, COSV99049230; called by muse, mutect2, varscan2
- SPATA31E1 | c.1811C>T p.P604L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as rs778879521, COSV57795812; called by muse, mutect2, varscan2
- STK32C | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV100061968; called by muse, mutect2, varscan2
- SUGP1 | c.1554G>T p.M518I | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99894704; called by muse, mutect2, varscan2
- TM9SF4 | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54109287, COSV99454061; called by muse, mutect2, varscan2
- TTN | c.30887C>A p.P10296Q (on ENST00000591111; = p.P9369Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | PolyPhen possibly damaging (0.779); catalogued as rs186731979, COSV100598485; called by muse, mutect2, varscan2
- USH2A | c.3590C>G p.S1197C | Missense Mutation (SNP) | VAF 84/141 reads (60%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.669); catalogued as COSV100230479; called by muse, mutect2, varscan2
- WDFY1 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs529647195, COSV51788263; called by muse, mutect2, varscan2
- WDR33 | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100459668, COSV59253751; called by muse, mutect2
- WLS | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as rs142863298; called by muse, mutect2, varscan2
- YBX2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1286928860, COSV99142658; called by muse, mutect2, varscan2
- ZHX1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV52877496; called by muse, mutect2, varscan2
- ZNF609 | c.1379G>A p.S460N | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.882); catalogued as COSV100440512; called by muse, mutect2, varscan2
- ZSCAN31 | c.381G>A p.Q127= | Splice Region (SNP) | VAF 100/264 reads (38%) | catalogued as COSV100716910; called by muse, mutect2, varscan2
- ANO4 | c.2195del p.L732Qfs*8 (on ENST00000392977 / NM_001286615.2; = p.L697Qfs*8 on NM_178826.4) | Frame Shift Del (DEL) | VAF 50/142 reads (35%) | called by mutect2, pindel, varscan2
- ATP11B | c.1582_1601del p.P529Rfs*15 | Frame Shift Del (DEL) | VAF 38/200 reads (19%) | called by mutect2, pindel
- BACH1 | c.1706_1707del p.I569Sfs*11 | Frame Shift Del (DEL) | VAF 10/19 reads (53%) | called by mutect2, pindel, varscan2
- CCDC174 | c.607del p.T203Pfs*7 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- CPA3 | c.848_863del p.T283Ifs*7 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | called by mutect2, pindel
- DSCAML1 | c.4923_4927del p.A1642Rfs*2 (on ENST00000321322; = p.A1582Rfs*2 on NM_020693.4) | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.1235_1238dup p.M413Ifs*7 | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- KMT2D | c.3465_3466del p.D1156Pfs*27 | Frame Shift Del (DEL) | VAF 42/98 reads (43%) | called by mutect2, pindel*, varscan2*
- PI4K2A | c.1419dup p.P474Afs*67 | Frame Shift Ins (INS) | VAF 15/98 reads (15%) | called by mutect2, pindel, varscan2
- WDR72 | c.2344_2358del p.P782_V786del | In Frame Del (DEL) | VAF 52/234 reads (22%) | called by mutect2, pindel
- ZNF41 | c.1058_1059del p.K353Tfs*6 | Frame Shift Del (DEL) | VAF 32/50 reads (64%) | called by mutect2, pindel, varscan2
- ASXL2 | c.2217T>A p.G739= | Silent (SNP) | VAF 42/179 reads (23%) | catalogued as COSV99710422; called by muse, mutect2, varscan2
- CYP3A5 | c.1434G>A p.T478= | Silent (SNP) | VAF 36/75 reads (48%) | catalogued as rs745883666, COSV56122722; called by muse, mutect2, varscan2
- DCDC1 | c.3804T>C p.N1268= (on ENST00000597505 / NM_001367979.1; = p.N375= on NM_020869.3) | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100337925; called by muse, mutect2
- DDX60 | c.135A>G p.S45= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs201139338, COSV101190294; called by muse, varscan2
- DHRS7C | c.33G>T p.L11= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV100364571; called by muse, mutect2
- DYTN | c.756C>T p.C252= | Silent (SNP) | VAF 55/85 reads (65%) | catalogued as rs999528540, COSV101510810; called by muse, mutect2, varscan2
- EIF3E | c.552A>G p.A184= | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as COSV99622855; called by muse, mutect2, varscan2
- FCRL5 | c.2412C>A p.S804= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV100708606; called by muse, mutect2, varscan2
- FLG | c.11430C>T p.S3810= | Silent (SNP) | VAF 179/508 reads (35%) | catalogued as rs1212417330, COSV100910809; called by muse, mutect2, varscan2
- ITIH2 | c.1824T>A p.I608= | Silent (SNP) | VAF 38/149 reads (26%) | catalogued as COSV64435465; called by muse, mutect2, varscan2
- KLHL35 | c.1503C>A p.I501= | Silent (SNP) | VAF 45/246 reads (18%) | catalogued as COSV66219514, COSV66219722; called by muse, mutect2, varscan2
- KLK3 | c.318G>A p.L106= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100385948; called by muse, mutect2, varscan2
- LAMB4 | c.2484A>G p.V828= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99223122; called by muse, mutect2, varscan2
- LCE2B | c.87C>T p.P29= | Silent (SNP) | VAF 70/155 reads (45%) | catalogued as COSV100909285; called by muse, mutect2, varscan2
- LRRC32 | c.1404G>A p.L468= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99476734; called by muse, mutect2
- MAP3K19 | c.1131C>A p.A377= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV100208183; called by muse, mutect2, varscan2
- MFSD14B | c.831C>G p.L277= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as COSV100942608, COSV64700781; called by muse, mutect2, varscan2
- MYH7 | c.4827C>T p.N1609= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs587781085, COSV62524994; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- OR10K2 | c.273C>A p.T91= | Silent (SNP) | VAF 60/165 reads (36%) | catalogued as COSV59220389; called by muse, mutect2, varscan2
- OR2T33 | c.21C>A p.T7= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as COSV100531681, COSV100531964; called by muse, mutect2, varscan2
- OR52E6 | c.798C>A p.G266= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100259163; called by muse, mutect2, varscan2
- PLSCR1 | c.489G>A p.R163= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV100678320; called by muse, mutect2, varscan2
- RIN3 | c.789G>A p.P263= | Silent (SNP) | VAF 121/239 reads (51%) | catalogued as rs201235572, COSV53651808; called by muse, mutect2, varscan2
- SKAP2 | c.696G>A p.E232= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs1354801441, COSV100591736; called by muse, mutect2, varscan2
- SLC10A6 | c.966G>A p.K322= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV56720572, COSV99907190; called by muse, mutect2, varscan2
- SLC8A1 | c.1203T>A p.T401= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as COSV100244966; called by muse, mutect2, varscan2
- SLC9A4 | c.369G>A p.P123= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as rs767431632, COSV99762779; called by muse, mutect2, varscan2
- TFAP2B | c.159C>T p.S53= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV53832649, COSV99539715; called by muse, mutect2, varscan2
- TG | c.6657T>A p.G2219= | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as COSV99599457; called by muse, mutect2, varscan2
- ZNF768 | c.1107C>T p.H369= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs758969203, COSV100776103; called by muse, mutect2, varscan2
- FAM27E5 | n.248C>G | RNA (SNP) | VAF 25/148 reads (17%) | called by muse, mutect2, varscan2
- GP6 | c.*320A>T | 3'UTR (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100117419; called by muse, mutect2, varscan2
- KIR3DX1 | n.600G>C | RNA (SNP) | VAF 36/122 reads (30%) | catalogued as COSV99683022; called by muse, mutect2, varscan2
- NDUFB1 | c.-184G>T | 5'UTR (SNP) | VAF 41/89 reads (46%) | catalogued as rs768770418, COSV100102627; called by muse, mutect2, varscan2
